Somatic mutation profile of tumor specimen TCGA-24-2288-01A (aliquot TCGA-24-2288-01A-01W-0799-08) from TCGA case TCGA-24-2288, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.7 years (25,831 days).
Specimen TCGA-24-2288-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d271948d-b7d0-462c-abf5-24d293e1d1d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2288-10A (Blood Derived Normal), aliquot TCGA-24-2288-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b946dc0c-a9cf-4ba1-95c2-da1227badf4a

The open-access MAF lists 179 somatic variants for this specimen: 137 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 39, Splice Site 3, Nonsense Mutation 3, Frame Shift Del 2, Translation Start Site 1, Nonstop Mutation 1, Splice Region 1, RNA 1, In Frame Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 189/325 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACTR6 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51842177; called by muse, mutect2
- ADAMTSL3 | c.2940C>A p.Y980* | Nonsense Mutation (SNP) | VAF 24/500 reads (5%) | catalogued as COSV54462352; called by muse, mutect2
- ADCY10 | c.3442G>T p.V1148L | Missense Mutation (SNP) | VAF 24/842 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV100896558; called by muse, mutect2
- AHNAK | c.3792G>C p.M1264I | Missense Mutation (SNP) | VAF 29/531 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.176); catalogued as COSV99945502; called by muse, mutect2
- ANKRD7 | c.748A>C p.K250Q | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV54555728; called by muse, mutect2
- ANO2 | c.2734C>G p.L912V (on ENST00000356134 / NM_001278597.3; = p.L916V on NM_001278596.3) | Missense Mutation (SNP) | VAF 54/1278 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.327); catalogued as COSV100499651, COSV100499750; called by muse, mutect2
- APOB | c.13337G>C p.R4446T | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as rs769871675, COSV51943767; called by muse, mutect2, varscan2
- APOB | c.4958C>A p.S1653Y | Missense Mutation (SNP) | VAF 27/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51943784; called by muse, mutect2, varscan2
- APP | c.2074G>T p.A692S | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); catalogued as COSV100695254; called by muse, mutect2
- ARHGAP24 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs533903357, COSV101232945; called by muse, mutect2
- BCHE | c.327G>C p.M109I | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV52259399; called by muse, mutect2
- CD209 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 80/826 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as rs11465393, COSV52653582; called by muse, mutect2
- CEP128 | c.1176C>A p.D392E | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.41); catalogued as COSV53676528; called by muse, mutect2, varscan2
- CHD4 | c.1702G>C p.D568H (on ENST00000357008 / NM_001363606.2; = p.D581H on NM_001273.5) | Missense Mutation (SNP) | VAF 201/754 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV100537313; called by muse, mutect2, varscan2
- CHPF2 | c.1400G>C p.S467T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.415); catalogued as COSV50394304; called by muse, mutect2, varscan2
- COL5A2 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.112); catalogued as COSV66411732; called by muse, mutect2, varscan2
- COL6A3 | c.5815C>G p.Q1939E | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV99796179; called by muse, mutect2, varscan2
- CPS1 | c.2309T>C p.V770A | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV99242138; called by muse, mutect2
- CRTAC1 | c.1331A>T p.N444I | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV54005172; called by muse, mutect2, varscan2
- CSMD3 | c.4099A>T p.S1367C (on ENST00000297405 / NM_001363185.1; = p.S1263C on NM_052900.3) | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV52243557; called by muse, mutect2, varscan2
- CUL9 | c.5188C>T p.R1730C | Missense Mutation (SNP) | VAF 64/754 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs779866234, COSV52727278; called by muse, mutect2
- DCTN2 | c.163G>C p.D55H (on ENST00000548249 / NM_001261413.2; = p.D60H on NM_006400.4) | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV71553243; called by muse, mutect2, varscan2
- DDX25 | c.1402A>G p.K468E | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99699632; called by muse, mutect2
- DNAH3 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV54535362; called by muse, mutect2, varscan2
- DNAJB4 | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66131897; called by muse, mutect2, varscan2
- DOP1A | c.3129T>C p.N1043= | Splice Region (SNP) | VAF 42/80 reads (53%) | catalogued as rs775703257, COSV52713573; called by muse, mutect2, varscan2
- DST | c.12533G>T p.S4178I (on ENST00000361203 / NM_001374722.1; = p.S1766I on NM_015548.5) | Missense Mutation (SNP) | VAF 21/362 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as COSV99750984; called by muse, mutect2
- EPC1 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV53927784; called by muse, mutect2, varscan2
- EPHB3 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57807532; called by muse, mutect2, varscan2
- EPS8 | c.1057A>G p.S353G | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs768776753, COSV55533641; called by muse, mutect2, varscan2
- ERO1B | c.768C>A p.S256R | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99934438; called by muse, mutect2
- ETS1 | c.569C>G p.P190R | Missense Mutation (SNP) | VAF 161/592 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.767); catalogued as rs540929701, COSV60095139; called by muse, mutect2, varscan2
- FAM118B | c.855G>C p.E285D | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV64157407; called by muse, mutect2, varscan2
- FOXP1 | c.235A>C p.S79R | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV100560899; called by muse, mutect2
- FPGT-TNNI3K | c.1213C>G p.Q405E | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.412); catalogued as COSV58559934; called by muse, mutect2, varscan2
- FREM1 | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 88/1162 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373156235, COSV63087444; called by muse, mutect2
- FRMPD2 | c.3157C>A p.R1053S | Missense Mutation (SNP) | VAF 195/399 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV59720698; called by muse, mutect2, varscan2
- GEN1 | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV58057574; called by muse, mutect2, varscan2
- GON4L | c.4858G>A p.D1620N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55195691; called by muse, mutect2, varscan2
- GRIA4 | c.2095G>C p.A699P | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV56907764; called by muse, mutect2, varscan2
- GSR | c.796G>C p.V266L | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.481); catalogued as COSV55321817; called by muse, mutect2, varscan2
- HAPLN1 | c.91C>G p.H31D | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99164548; called by muse, mutect2
- HSPG2 | c.11195G>A p.R3732K | Missense Mutation (SNP) | VAF 80/103 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs745888061, COSV65933550; called by muse, mutect2, varscan2
- HTR2C | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 146/1024 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1316757499, COSV99348076; called by muse, varscan2
- HTT | c.7258T>A p.W2420R | Missense Mutation (SNP) | VAF 23/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61865478; called by muse, mutect2
- IFT122 | c.1147+1G>T p.X383_splice (on ENST00000348417 / NM_052989.3; = p.X324_splice on NM_018262.4) | Splice Site (SNP) | VAF 96/235 reads (41%) | catalogued as rs778752583, COSV56205424; called by muse, mutect2, varscan2
- ILF3 | c.713C>G p.T238S | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.45); PolyPhen benign (0.1); catalogued as COSV51560089; called by muse, varscan2
- IRAK3 | c.1033T>C p.Y345H | Missense Mutation (SNP) | VAF 29/424 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99705885; called by muse, mutect2
- ITIH2 | c.1972G>A p.G658S | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs769353040, COSV100623154; called by muse, mutect2, varscan2
- KCNH1 | c.1684G>T p.D562Y (on ENST00000271751 / NM_172362.3; = p.D535Y on NM_002238.4) | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99657250, COSV99660033; called by muse, mutect2
- KDM3B | c.4429G>C p.D1477H | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100069164; called by muse, mutect2
- KIAA0232 | c.2456G>C p.G819A | Missense Mutation (SNP) | VAF 30/526 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV100300361; called by muse, mutect2
- KIT | c.920T>G p.V307G | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99853250; called by muse, mutect2
- KMT2A | c.9606C>A p.S3202R | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); catalogued as COSV63282414, COSV63289423; called by muse, mutect2, varscan2
- LAMA4 | c.1477G>C p.D493H (on ENST00000230538 / NM_001105206.3; = p.D486H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/482 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV57895273; called by muse, mutect2
- LCE2C | c.332G>C p.*111Sext*10 | Nonstop Mutation (SNP) | VAF 14/140 reads (10%) | catalogued as rs768048704, COSV100909385; called by muse, mutect2
- LCE3D | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/352 reads (6%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.916); catalogued as rs774469152, COSV100909798; called by muse, mutect2
- LIG4 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as rs1246340932, COSV63597550; called by muse, mutect2, varscan2
- MACF1 | c.10453G>C p.V3485L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as COSV57131986; called by muse, mutect2, varscan2
- MAGEA11 | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 61/86 reads (71%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.733); catalogued as rs782337606, COSV100290376; called by muse, mutect2, varscan2
- MAMLD1 | c.1162C>G p.L388V | Missense Mutation (SNP) | VAF 73/347 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53378021; called by muse, mutect2, varscan2
- MCF2L2 | c.3023C>G p.S1008C | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100191212, COSV100193536; called by muse, mutect2
- METAP1 | c.380A>C p.Q127P | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99595365; called by muse, mutect2, varscan2
- MFN1 | c.1451T>C p.L484P | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54941001; called by muse, mutect2, varscan2
- MUC16 | c.9424G>A p.E3142K | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as rs1316096447, COSV67456664, COSV67479393; called by muse, mutect2, varscan2
- MYO3A | c.976A>G p.K326E | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV99778281; called by muse, mutect2
- NIM1K | c.771G>C p.L257F | Missense Mutation (SNP) | VAF 105/294 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58143570; called by muse, mutect2, varscan2
- NLRP13 | c.344A>C p.Q115P | Missense Mutation (SNP) | VAF 261/690 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61623018; called by muse, mutect2, varscan2
- NME1-NME2 | c.559C>A p.H187N (on ENST00000555572; = p.H162N on NM_001018136.3) | Missense Mutation (SNP) | VAF 46/508 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as COSV64510709; called by muse, mutect2
- NSD3 | c.824G>C p.W275S | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV57620558; called by muse, mutect2, varscan2
- NTRK2 | c.2457C>G p.D819E (on ENST00000323115 / NM_001369534.1; = p.D835E on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/591 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99452299; called by muse, mutect2
- NUP205 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 13/282 reads (5%) | catalogued as COSV53657041; called by muse, mutect2
- NUP210 | c.4816G>C p.E1606Q | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs774007395, COSV54409599; called by muse, mutect2, varscan2
- OR10C1 | c.926C>T p.T309M (on ENST00000622521; = p.T307M on NM_013941.3) | Missense Mutation (SNP) | VAF 70/465 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs142718527; called by muse, mutect2, varscan2
- OR4C46 | c.774A>T p.R258S | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as COSV60220395; called by muse, mutect2
- OR4K13 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59860167; called by muse, mutect2, varscan2
- OR8H3 | c.61T>G p.S21A | Missense Mutation (SNP) | VAF 36/854 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100538732; called by muse, mutect2
- OTOGL | c.6844T>G p.C2282G (on ENST00000547103; = p.C2273G on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086666; called by muse, mutect2, varscan2
- PAG1 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV99596974; called by muse, mutect2
- PLCB4 | c.238T>G p.L80V | Missense Mutation (SNP) | VAF 33/686 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV99594305; called by muse, mutect2
- PLCH1 | c.2110T>G p.C704G (on ENST00000340059 / NM_001130960.2; = p.C716G on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 206/443 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV58203988; called by muse, mutect2, varscan2
- PLEKHG1 | c.2410C>A p.P804T | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV62049113; called by muse, mutect2, varscan2
- POM121C | c.2680G>A p.D894N (on ENST00000607367; = p.D652N on NM_001099415.3) | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.103); catalogued as rs1198305597; called by muse, mutect2, varscan2
- PPARGC1B | c.153C>A p.D51E | Missense Mutation (SNP) | VAF 92/320 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58531199; called by muse, mutect2
- PTGIS | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 116/309 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV54838803; called by muse, mutect2, varscan2
- PTPRN | c.271A>C p.M91L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV55347762, COSV99833671; called by muse, mutect2
- REG4 | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 167/1273 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56653631; called by muse, mutect2, varscan2
- RFWD3 | c.2054A>C p.Q685P | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV100736173; called by muse, mutect2
- RNF182 | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 32/1258 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV101337840; called by muse, mutect2
- ROBO2 | c.2727-1G>T p.X909_splice | Splice Site (SNP) | VAF 11/178 reads (6%) | catalogued as COSV99046052; called by muse, mutect2
- RSBN1L | c.2049T>A p.S683R | Missense Mutation (SNP) | VAF 102/398 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58509636; called by muse, mutect2, varscan2
- SCARF1 | c.1561G>T p.D521Y | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53961078, COSV99556847; called by muse, mutect2, varscan2
- SEPTIN4 | c.1066T>A p.S356T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.334); catalogued as COSV100400210; called by muse, mutect2
- SFMBT2 | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV62812903; called by muse, mutect2, varscan2
- SI | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV100013919; called by muse, mutect2
- SIGLEC14 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 28/552 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV55783955, COSV99707093; called by muse, mutect2
- SKAP2 | c.1048A>G p.K350E | Missense Mutation (SNP) | VAF 127/184 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61725368; called by muse, varscan2
- SLC10A1 | c.280T>G p.L94V | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53683180; called by muse, mutect2, varscan2
- SLC12A6 | c.3185C>T p.A1062V (on ENST00000354181 / NM_001365088.1; = p.A1011V on NM_005135.2) | Missense Mutation (SNP) | VAF 251/490 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs779629182, COSV51624831; called by muse, mutect2, varscan2
- SLC28A1 | c.1069T>C p.Y357H | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99722544; called by muse, mutect2
- SLC39A12 | c.1420A>G p.K474E | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV66200537; called by muse, mutect2, varscan2
- SLC45A2 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 125/388 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV56873482; called by muse, mutect2, varscan2
- SLC5A12 | c.1322G>C p.G441A | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101237555; called by muse, mutect2
- SLC9C1 | c.1388T>A p.L463H | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99997289; called by muse, mutect2
- SLCO1B3 | c.361T>G p.Y121D | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99680766; called by muse, mutect2
- SLITRK4 | c.2315T>C p.I772T | Missense Mutation (SNP) | VAF 80/108 reads (74%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV62025122; called by muse, mutect2, varscan2
- SPEN | c.7070C>A p.P2357H | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.048); catalogued as COSV101004997; called by muse, mutect2
- SPHKAP | c.4954G>C p.E1652Q (on ENST00000392056 / NM_001142644.2; = p.E1623Q on NM_030623.3) | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV60875548, COSV60886813; called by muse, mutect2, varscan2
- ST18 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 32/523 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs763683207, COSV52509315; called by muse, mutect2
- STARD5 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371611066; called by muse, mutect2
- STT3A | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV101205106; called by muse, mutect2
- SVOP | c.833T>A p.L278* | Nonsense Mutation (SNP) | VAF 50/1126 reads (4%) | catalogued as COSV100139182; called by muse, mutect2
- TACC2 | c.5800C>G p.P1934A | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57763172; called by muse, mutect2, varscan2
- TANC1 | c.4346G>T p.G1449V | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.036); catalogued as COSV55092109; called by muse, mutect2, varscan2
- TANC1 | c.5476C>G p.L1826V | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55092121; called by muse, mutect2, varscan2
- TBC1D9B | c.2366A>C p.Q789P | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100783429; called by muse, mutect2
- TENM2 | c.7003G>C p.V2335L (on ENST00000518659 / NM_001122679.2; = p.V2096L on NM_001080428.3) | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.391); catalogued as COSV101317783; called by muse, mutect2
- TG | c.4855T>G p.S1619A | Missense Mutation (SNP) | VAF 95/2388 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV99598977; called by muse, mutect2
- TMEM39B | c.1063G>C p.G355R | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60380206, COSV60381713; called by muse, mutect2, varscan2
- TTF1 | c.1751G>T p.R584M | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100524446; called by muse, mutect2
- TYW1 | c.1216C>G p.R406G | Missense Mutation (SNP) | VAF 142/1022 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs377758713, COSV62753933; called by muse, varscan2
- USF3 | c.1679C>A p.T560N | Missense Mutation (SNP) | VAF 178/584 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); catalogued as COSV57075068; called by muse, mutect2, varscan2
- USP21 | c.872T>G p.V291G | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99237123; called by muse, mutect2
- VDR | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV57469159; called by muse, mutect2, varscan2
- ZBTB47 | c.1771C>G p.L591V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51765108; called by muse, mutect2, varscan2
- ZC3H13 | c.273C>G p.N91K | Missense Mutation (SNP) | VAF 23/538 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99667436; called by muse, mutect2
- ZNF223 | c.142+1G>A p.X48_splice | Splice Site (SNP) | VAF 30/832 reads (4%) | catalogued as COSV101462600; called by muse, mutect2
- ZNF248 | c.1382A>G p.E461G | Missense Mutation (SNP) | VAF 131/732 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61998087; called by muse, mutect2, varscan2
- ZNF439 | c.25_27del p.L9del | In Frame Del (DEL) | VAF 17/206 reads (8%) | catalogued as rs775000805; called by pindel, varscan2*
- ZNF654 | c.2546C>A p.P849Q | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100525593; called by muse, mutect2
- ZSCAN2 | c.1628C>A p.S543Y | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV100306829; called by muse, mutect2
- AATF | c.540G>C p.M180I | Missense Mutation (SNP) | VAF 71/94 reads (76%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DST | c.10728del p.F3576Lfs*23 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | called by mutect2, pindel, varscan2
- MRC1 | c.2926G>A p.A976T | Missense Mutation (SNP) | VAF 32/752 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2
- MSH2 | c.2252del p.G751Efs*12 | Frame Shift Del (DEL) | VAF 98/209 reads (47%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.1309C>G p.L437V | Missense Mutation (SNP) | VAF 98/1285 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABL2 | c.210C>T p.G70= (on ENST00000502732 / NM_007314.4; = p.G55= on NM_005158.5) | Silent (SNP) | VAF 69/744 reads (9%) | catalogued as COSV61017647; called by muse, mutect2
- AFAP1L1 | c.1245C>A p.T415= | Silent (SNP) | VAF 30/368 reads (8%) | catalogued as COSV57046456; called by muse, mutect2
- ARMC8 | c.477G>A p.R159= (on ENST00000469044 / NM_001363941.2; = p.R145= on NM_014154.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/237 reads (5%) | catalogued as COSV61769203; called by muse, mutect2
- BTBD7 | c.2889C>T p.R963= | Silent (SNP) | VAF 22/188 reads (12%) | catalogued as COSV58288580; called by muse, mutect2, varscan2
- CAPN1 | c.1497C>A p.S499= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99658351; called by muse, mutect2
- CCDC39 | c.1923A>G p.R641= | Silent (SNP) | VAF 128/237 reads (54%) | catalogued as rs768294232, COSV56488585; called by muse, mutect2, varscan2
- CELSR3 | c.876G>A p.G292= | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as rs1468625679, COSV50924920; called by muse, mutect2, varscan2
- COL7A1 | c.5589C>T p.G1863= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs201871749, COSV60398529; called by muse, mutect2, varscan2
- DST | c.8991A>G p.L2997= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV99750989; called by muse, mutect2
- DZIP3 | c.1914C>T p.T638= | Silent (SNP) | VAF 15/227 reads (7%) | catalogued as COSV100847614; called by muse, mutect2
- FAT3 | c.7446G>A p.V2482= | Silent (SNP) | VAF 14/211 reads (7%) | catalogued as COSV99961769; called by muse, mutect2
- GDF11 | c.270G>A p.K90= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV57690202; called by muse, mutect2
- GUCY1B1 | c.1329C>G p.A443= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as COSV100025857, COSV52377135; called by muse, mutect2, varscan2
- HDC | c.1029C>T p.A343= | Silent (SNP) | VAF 124/352 reads (35%) | catalogued as COSV51074668; called by muse, mutect2, varscan2
- KNCN | c.39G>T p.L13= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV53815174; called by muse, mutect2, varscan2
- MS4A2 | c.117G>A p.L39= | Silent (SNP) | VAF 14/292 reads (5%) | catalogued as rs911864282, COSV54012122; called by muse, mutect2
- MUC17 | c.2958A>C p.T986= | Silent (SNP) | VAF 62/930 reads (7%) | catalogued as COSV100071563; called by muse, mutect2
- MYBPC1 | c.3360A>G p.K1120= (on ENST00000550270 / NM_206820.2; = p.K1127= on NM_002465.4) | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as COSV62255199; called by muse, mutect2, varscan2
- MYF5 | c.279G>C p.R93= | Silent (SNP) | VAF 4/81 reads (5%) | catalogued as COSV99953106; called by muse, mutect2
- NAV1 | c.2766G>A p.L922= | Silent (SNP) | VAF 18/294 reads (6%) | catalogued as rs186967823, COSV99818171; called by muse, mutect2
- OR5AC2 | c.394T>C p.L132= | Silent (SNP) | VAF 33/797 reads (4%) | catalogued as COSV62279216; called by muse, mutect2
- PCDHGB4 | c.1971G>A p.T657= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV53986868; called by muse, mutect2, varscan2
- PGK2 | c.957G>A p.E319= | Silent (SNP) | VAF 18/567 reads (3%) | catalogued as rs1207367286, COSV100505328; called by muse, mutect2
- PSORS1C2 | c.174C>G p.P58= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV52536073; called by muse, mutect2, varscan2
- RGS3 | c.576C>A p.T192= (on ENST00000350696 / NM_001282923.2; = p.T80= on NM_017790.4) | Silent (SNP) | VAF 10/225 reads (4%) | catalogued as COSV100464545, COSV58286480; called by muse, mutect2
- SEC24C | c.723G>C p.V241= | Silent (SNP) | VAF 20/443 reads (5%) | catalogued as COSV100226499; called by muse, mutect2
- SLC38A4 | c.666T>G p.L222= | Silent (SNP) | VAF 104/279 reads (37%) | catalogued as COSV56969246; called by muse, mutect2, varscan2
- SLITRK1 | c.708C>T p.I236= | Silent (SNP) | VAF 57/115 reads (50%) | catalogued as rs779610480, COSV65675226; called by muse, mutect2, varscan2
- SRCAP | c.4521A>C p.L1507= | Silent (SNP) | VAF 65/381 reads (17%) | catalogued as COSV52676700; called by muse, mutect2, varscan2
- SSMEM1 | c.474A>G p.E158= | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as COSV52833878; called by muse, mutect2, varscan2
- SULT1C2 | c.129C>A p.L43= | Silent (SNP) | VAF 87/353 reads (25%) | catalogued as COSV52265956; called by muse, mutect2, varscan2
- SYT16 | c.1524G>A p.E508= | Silent (SNP) | VAF 23/288 reads (8%) | catalogued as COSV101413485; called by muse, mutect2
- TADA2B | c.585C>T p.D195= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs945704210, COSV53827597; called by muse, mutect2
- TIGD6 | c.291T>C p.T97= | Silent (SNP) | VAF 22/220 reads (10%) | catalogued as COSV57061403; called by muse, mutect2
- TOP1 | c.1749C>G p.G583= | Silent (SNP) | VAF 26/216 reads (12%) | catalogued as COSV63694966; called by muse, mutect2, varscan2
- TSHZ3 | c.1800C>A p.S600= | Silent (SNP) | VAF 26/638 reads (4%) | catalogued as COSV99550607; called by muse, mutect2
- TTN | c.1158G>T p.V386= | Silent (SNP) | VAF 22/550 reads (4%) | catalogued as COSV100593767; called by muse, mutect2
- VCAN | c.5727A>G p.S1909= | Silent (SNP) | VAF 338/492 reads (69%) | catalogued as COSV54110556; called by muse, mutect2, varscan2
- ZNF347 | c.255C>A p.I85= | Silent (SNP) | VAF 592/1730 reads (34%) | catalogued as COSV100498116; called by muse, mutect2, varscan2
- MAP4K1 | c.*28C>T | 3'UTR (SNP) | VAF 64/247 reads (26%) | catalogued as COSV62103428; called by muse, mutect2, varscan2
- RPL26P30 | n.689C>A | RNA (SNP) | VAF 78/111 reads (70%) | called by muse, mutect2, varscan2
- YWHAH | c.87+5526A>T | Intron (SNP) | VAF 21/128 reads (16%) | catalogued as COSV99963717; called by muse, mutect2, varscan2
